CPTAC case 11BR050 — Breast — Cystic, Mucinous and Serous Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/5978194e-dfd2-4666-b716-a0f7d6e36566

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Mucinous carcinoma: ICD-O-3 morphology code: 8480/3; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 54.0 years (19,709 days); AJCC pathologic stage: Stage IIA; Prior malignancy: no.

Biospecimens (2 samples)
- Sample d5298917-e497-4c47-a604-645708: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Sample d8a5467b-549b-48ed-9ae5-c9c39d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
